Somatic mutation profile of tumor specimen TCGA-BR-7715-01A (aliquot TCGA-BR-7715-01A-11D-2053-08) from TCGA case TCGA-BR-7715, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.3 years (23,861 days).
Specimen TCGA-BR-7715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9affaafd-c904-40f3-b548-84fd743af2d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7715-10A (Blood Derived Normal), aliquot TCGA-BR-7715-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c119cc02-9f2c-43bf-bfcd-b5856e86899d

The open-access MAF lists 143 somatic variants for this specimen: 108 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 30, Nonsense Mutation 4, Intron 4, Frame Shift Del 3, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 9/13 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs765498811, COSV60680329; called by muse, mutect2, varscan2
- ABLIM1 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 155/388 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV53299704; called by muse, mutect2, varscan2
- AC126283.2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1231181254, COSV67097851; called by muse, mutect2, varscan2
- ADAM23 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 52/123 reads (42%) | catalogued as rs1195575532, COSV52207862; called by muse, mutect2, varscan2
- ADAMTS20 | c.3931G>A p.G1311R | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1000723243, COSV67126082; called by muse, mutect2, varscan2
- ADRB1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65167625; called by muse, mutect2, varscan2
- AKNA | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV56311036; called by muse, mutect2, varscan2
- ARFGAP2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54065132; called by muse, mutect2, varscan2
- ARHGEF1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs1413353058, COSV61526285; called by muse, mutect2
- ATP10D | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs766319846, COSV56703890; called by muse, mutect2, varscan2
- ATP2B2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59489151; called by muse, mutect2, varscan2
- ATP2B3 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs782459941, COSV54840389; called by muse, mutect2, varscan2
- CABS1 | c.222A>C p.K74N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV56732935, COSV56734791, COSV99909251; called by muse, mutect2, varscan2
- CENPE | c.4901C>T p.T1634I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV54376100; called by muse, mutect2, varscan2
- CFAP77 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs199572965, COSV58007206; called by muse, mutect2, varscan2
- CHI3L1 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1263744475, COSV55137091; called by muse, mutect2
- CNGA1 | c.1908G>T p.R636S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV62052954; called by muse, mutect2, varscan2
- COL6A3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV55082709, COSV55091896; called by muse, mutect2
- CPXM1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as rs778161412, COSV66044608; called by muse, mutect2
- CRMP1 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs187171314, COSV61478219; called by muse, mutect2, varscan2
- CSE1L | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53700397; called by muse, mutect2
- CSNK1A1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 67/92 reads (73%) | catalogued as COSV55792773; called by muse, mutect2, varscan2
- CUBN | c.4391A>G p.Q1464R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as COSV64707862; called by muse, mutect2, varscan2
- CYP46A1 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55893033; called by muse, mutect2
- DCC | c.3839G>A p.R1280Q | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs1468620860, COSV71425788; called by muse, mutect2, varscan2
- DCDC1 | c.2110A>C p.I704L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100663028; called by muse, mutect2
- DDX1 | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51837992; called by muse, mutect2
- DLGAP1 | c.2276C>T p.T759M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1027822448, COSV59784080; called by muse, mutect2, varscan2
- DNAH7 | c.1357A>C p.S453R | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV56751945; called by muse, mutect2, varscan2
- DTWD1 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52071012; called by muse, mutect2, varscan2
- DUOX2 | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747720952, CM159748, COSV66530615; called by mutect2, varscan2
- ENPP7 | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV60385319; called by muse, mutect2
- F7 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.089); catalogued as rs775296543, COSV60644988; called by muse, mutect2
- FBXO11 | c.2681C>T p.T894I (on ENST00000403359 / NM_001190274.2; = p.T810I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52274280; called by muse, mutect2, varscan2
- FSTL5 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 200/309 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60181675, COSV60203884; called by muse, mutect2, varscan2
- GREB1 | c.3271G>T p.A1091S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as COSV52180640; called by muse, varscan2
- HAS1 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55788251; called by muse, mutect2, varscan2
- HOXA4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57825075; called by muse, mutect2, varscan2
- HRNR | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.092); catalogued as COSV64254203; called by muse, mutect2, varscan2
- ICE1 | c.843T>G p.N281K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.058); catalogued as COSV56819106; called by muse, mutect2, varscan2
- IKZF4 | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV56266770; called by muse, mutect2, varscan2
- IL1R2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1299459804, COSV60205654; called by muse, mutect2, varscan2
- IRF2 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66928511; called by muse, mutect2, varscan2
- JAKMIP1 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51522322; called by muse, mutect2, varscan2
- KCNK18 | c.8T>G p.V3G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57970918; called by muse, mutect2, varscan2
- KIFAP3 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV63031043; called by muse, mutect2, varscan2
- MCM3AP | c.1928A>C p.E643A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52436299; called by muse, mutect2
- MED12 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV61331494; called by muse, mutect2
- MID2 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV53306832; called by muse, mutect2, varscan2
- MPP3 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs202078532; called by muse, mutect2, varscan2
- MSL2 | c.1013T>C p.L338S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as COSV53859630; called by muse, mutect2, varscan2
- MYO15A | c.9556T>G p.L3186V | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as COSV52751794; called by muse, mutect2, varscan2
- NDN | c.698A>C p.K233T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59358446; called by muse, mutect2, varscan2
- NFXL1 | c.2223C>G p.I741M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs774605626, COSV100216793, COSV61197999, COSV61200125; called by muse, varscan2
- NLK | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63490529, COSV63490628; called by muse, mutect2, varscan2
- OR10J3 | c.600C>A p.N200K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as rs368451074; called by muse, mutect2, varscan2
- OR1L1 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as COSV58935209; called by muse, mutect2, varscan2
- OR2M7 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58737746; called by muse, mutect2, varscan2
- OR51F2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202173777, COSV59063723; called by muse, mutect2, varscan2
- OR8H2 | c.894A>C p.K298N | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV57943134; called by muse, mutect2, varscan2
- OSCP1 | c.416C>T p.S139F (on ENST00000356637 / NM_001330493.1; = p.S129F on NM_145047.5) | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV52484842; called by muse, mutect2, varscan2
- OSGIN2 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52407109; called by muse, mutect2, varscan2
- PCDH18 | c.1742T>G p.L581W | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV61266410; called by muse, mutect2, varscan2
- PCDHGB3 | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV53898858; called by muse, mutect2, varscan2
- PDZD2 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765814114, COSV56850789; called by muse, mutect2, varscan2
- PIGS | c.632A>C p.D211A | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.372); catalogued as COSV52023424; called by muse, mutect2, varscan2
- PITX2 | c.452T>A p.L151Q (on ENST00000354925 / NM_001204397.1; = p.L158Q on NM_000325.6) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60740208; called by muse, mutect2, varscan2
- PKMYT1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs866197276, COSV51890841; called by muse, mutect2, varscan2
- PLAGL2 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55787397; called by muse, mutect2, varscan2
- PLEKHA6 | c.1593+1del p.X531_splice | Splice Site (DEL) | VAF 21/51 reads (41%) | catalogued as COSV99692684; called by mutect2, pindel, varscan2
- PNMT | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs748756615, COSV54092355; called by muse, mutect2, varscan2
- POM121C | c.956G>T p.R319L (on ENST00000607367; = p.R77L on NM_001099415.3) | Missense Mutation (SNP) | VAF 105/432 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV57544085; called by muse, mutect2, varscan2
- PRMT6 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV63654969; called by muse, mutect2
- RBM47 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55930153; called by muse, mutect2, varscan2
- RDH8 | c.908G>A p.R303H (on ENST00000651512; = p.R283H on NM_015725.4) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs201181546, COSV50673915; called by muse, mutect2
- RELN | c.9577A>G p.I3193V | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs765872977, COSV58985931; called by muse, mutect2, varscan2
- RFX6 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60583470, COSV60587880; called by muse, mutect2
- SCN1A | c.4405T>C p.F1469L (on ENST00000303395 / NM_001202435.3; = p.F1458L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV57660132; called by muse, mutect2, varscan2
- SDK1 | c.3155G>T p.G1052V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67356658; called by muse, mutect2, varscan2
- SEMA7A | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs767503529, COSV56089266; called by muse, mutect2, varscan2
- SGIP1 | c.1850A>C p.N617T | Missense Mutation (SNP) | VAF 94/159 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52762934; called by muse, mutect2, varscan2
- SH3D21 | c.1322_1323del p.V441Gfs*25 (on ENST00000453908 / NM_001162530.2; = p.V330Gfs*25 on NM_024676.5) | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs754388570; called by pindel, varscan2
- SLC22A25 | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60594474; called by muse, mutect2, varscan2
- SLC9C2 | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62943813, COSV62948813; called by muse, mutect2, varscan2
- SLITRK4 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as rs782237496, COSV62022135; called by muse, mutect2, varscan2
- SMG5 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.902); catalogued as rs1016477977, COSV62433990; called by muse, mutect2, varscan2
- SMTN | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs186264655, COSV60775190; called by muse, mutect2, varscan2
- SOGA3 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64105059; called by muse, mutect2, varscan2
- SPAG16 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55983306, COSV55987220; called by muse, mutect2
- SPATS2L | c.1202A>C p.K401T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62345393; called by muse, mutect2, varscan2
- SPTLC3 | c.1491A>C p.E497D | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV65463699; called by muse, mutect2, varscan2
- STYXL2 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54802031; called by muse, mutect2, varscan2
- SVEP1 | c.5412T>G p.I1804M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV52835461; called by muse, mutect2, varscan2
- SYNE1 | c.11760A>C p.K3920N | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.165); catalogued as COSV54907040; called by muse, mutect2, varscan2
- TANGO6 | c.2473A>G p.T825A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55760347; called by muse, mutect2, varscan2
- TP53BP2 | c.2279A>G p.Y760C (on ENST00000343537 / NM_001031685.3; = p.Y631C on NM_005426.2) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423967492, COSV59066335; called by muse, mutect2, varscan2
- TRANK1 | c.6292T>G p.F2098V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV57140470; called by muse, mutect2, varscan2
- TTLL7 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs770197943, COSV53081425, COSV99552775; called by muse, mutect2, varscan2
- TTN | c.49014G>T p.K16338N (on ENST00000591111; = p.K8914N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | PolyPhen benign (0.401); catalogued as COSV100602029; called by muse, mutect2
- TULP3 | c.528A>T p.Q176H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV101237465, COSV68117325, COSV68117820; called by muse, mutect2, varscan2
- USP26 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 114/139 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as rs777822476, COSV63708046; called by muse, mutect2, varscan2
- VWF | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1022679972, COSV54611681; called by muse, mutect2, varscan2
- XPO4 | c.3393G>T p.M1131I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55004029; called by muse, mutect2
- YY1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51761013; called by muse, mutect2, varscan2
- ZEB2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752377563, COSV57951453; called by muse, mutect2, varscan2
- GTSF1L | c.194del p.N65Tfs*14 | Frame Shift Del (DEL) | VAF 27/142 reads (19%) | called by mutect2, pindel, varscan2
- LRRC10 | c.351del p.S118Afs*26 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.432G>A p.V144= | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as COSV54652406; called by muse, mutect2
- AGAP2 | c.1818C>T p.S606= (on ENST00000547588 / NM_001122772.2; = p.S270= on NM_014770.4) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs201319391, COSV57726788; called by muse, mutect2, varscan2
- AGRN | c.2424C>T p.A808= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1553176121, COSV65067721; ClinVar: likely benign; called by muse, mutect2
- ANKRD30A | c.3051A>G p.K1017= (on ENST00000611781; = p.K961= on NM_052997.2) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV64603900, COSV64607723, COSV64608830; called by muse, mutect2, varscan2
- ARHGEF12 | c.2619C>T p.S873= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs772799606, COSV63102572; called by muse, mutect2, varscan2
- BRINP3 | c.1845G>A p.G615= | Silent (SNP) | VAF 90/469 reads (19%) | catalogued as COSV66513599; called by muse, mutect2, varscan2
- CA3 | c.219T>G p.T73= | Silent (SNP) | VAF 98/154 reads (64%) | catalogued as COSV53409214; called by muse, mutect2, varscan2
- CPAMD8 | c.4593C>T p.D1531= (on ENST00000651564; = p.D1484= on NM_015692.5) | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs756523203, COSV71595783; called by muse, mutect2, varscan2
- DCAF12L1 | c.771C>T p.I257= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV64421179; called by muse, mutect2, varscan2
- DISP1 | c.579G>A p.L193= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as COSV52654616; called by muse, mutect2
- EGFR | c.1740C>A p.I580= | Silent (SNP) | VAF 34/206 reads (17%) | catalogued as COSV51771345; called by muse, mutect2, varscan2
- G6PC2 | c.354C>T p.G118= | Silent (SNP) | VAF 84/519 reads (16%) | catalogued as rs185108752, COSV56371540; called by muse, mutect2, varscan2
- GLI3 | c.2568G>A p.S856= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV67885079; called by muse, mutect2, varscan2
- IGFALS | c.1020T>C p.L340= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs766794132, COSV51904637; called by muse, mutect2, varscan2
- INTS12 | c.321C>T p.D107= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV60861610; called by muse, mutect2
- KRT13 | c.252T>C p.G84= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV55839045, COSV55840604; called by muse, mutect2, varscan2
- LSAMP | c.369A>G p.Q123= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV61275870; called by muse, varscan2
- MECOM | c.219G>A p.T73= (on ENST00000468789 / NM_001105078.4; = p.T261= on NM_004991.4) | Silent (SNP) | VAF 85/234 reads (36%) | catalogued as rs150481592; called by muse, mutect2, varscan2
- MYBPC2 | c.2142C>T p.F714= | Silent (SNP) | VAF 80/121 reads (66%) | catalogued as rs371647573; called by muse, mutect2, varscan2
- NLRP8 | c.2976G>A p.A992= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs111647316, COSV52583161, COSV99405537; called by muse, mutect2, varscan2
- OLFM4 | c.786C>T p.L262= | Silent (SNP) | VAF 35/272 reads (13%) | catalogued as rs757133174, COSV54575780; called by muse, mutect2, varscan2
- OR9A2 | c.630G>A p.T210= | Silent (SNP) | VAF 49/157 reads (31%) | catalogued as rs375038215; called by muse, mutect2, varscan2
- PCDHB2 | c.1752G>A p.P584= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- PCDHB8 | c.1611C>T p.R537= | Silent (SNP) | VAF 14/300 reads (5%) | catalogued as rs1233212282, COSV50757947; called by muse, mutect2
- PCDHGB5 | c.1887C>T p.G629= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54019298; called by muse, mutect2, varscan2
- PDGFD | c.183C>T p.N61= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as rs148454316; called by muse, mutect2, varscan2
- ROPN1L | c.280T>C p.L94= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV56872992; called by muse, mutect2
- SBK1 | c.414C>T p.D138= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV59395952; called by muse, mutect2, varscan2
- SCARF2 | c.1959G>A p.S653= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV56731115; called by muse, mutect2
- SMC3 | c.66C>G p.P22= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV62418912; called by muse, mutect2, varscan2
- ATG16L1 | c.954+1103_954+1108del | Intron (DEL) | VAF 15/163 reads (9%) | called by mutect2, pindel
- CSH1 | c.456+126A>C | Intron (SNP) | VAF 22/190 reads (12%) | catalogued as rs1169175770, COSV100298270; called by muse, mutect2
- NFASC | c.2471-1347T>C | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs778825300, COSV100363298; called by muse, mutect2, varscan2
- RIMS2 | c.1692+258A>G | Intron (SNP) | VAF 34/124 reads (27%) | catalogued as COSV51667832, COSV99199464; called by muse, mutect2, varscan2
- SNORD3B-2 | n.171T>G | RNA (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
